CCDI case PBBPUW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/1f2449b0-b87c-4885-af75-4b64f7405d96

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.1 years (3,336 days).

Biospecimens (2 samples)
- Sample 0DEHMZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEHPC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
